MMRF case MMRF_1425 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4ee39eb6-8443-41e5-a916-5fe87f139370

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Dead; Days to death: 1,260 days (3.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.9 years (27,357 days); ISS stage: III; Days to last known disease status: 1,260 days (3.4 years); Days to last follow up: 1,260 days (3.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 108 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 227 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 115 days; Days to treatment end: 227 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 227 days; Days to treatment end: 1,107 days (3.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 237 days; Days to treatment end: 1,260 days (3.4 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,260.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 229 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 37.3 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 29.3 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 5.39 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 834 µmol/L; Blood Urea Nitrogen 20 mmol/L; Calcium 2.23 mmol/L; Albumin 25 g/L; Total Protein 7.4 g/dL; Glucose 4.51 mmol/L; C-Reactive Protein 2.24 mg/dL.
- Day 101 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 6.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.57 mg/dL; Immunoglobulin G 9.46 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.81 g/L; Hemoglobin 5.83 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 583 µmol/L; Blood Urea Nitrogen 16.8 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.
- Day 161 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.05 mg/dL; Immunoglobulin G 6.77 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 8.23 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 663 µmol/L; Blood Urea Nitrogen 18.6 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 269 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 7.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.62 mg/dL; Immunoglobulin G 8.17 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 1.12 g/L; Lactate Dehydrogenase 9.32 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 286 ×10⁹/L; Creatinine 690 µmol/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L.
- Day 367 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 8.9 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 7.75 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 592 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 4.73 mmol/L.
- Day 463: Serum Free Immunoglobulin Light Chain, Kappa 5.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.49 mg/dL; Immunoglobulin G 7.79 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.8 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 628 µmol/L; Blood Urea Nitrogen 16.1 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 4.79 mmol/L.
- Day 568: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.04 mg/dL; Immunoglobulin G 6.13 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.79 g/L; Hemoglobin 4.71 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 424 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 30 g/L; Total Protein 5.8 g/dL; Glucose 5.61 mmol/L.
- Day 631: Serum Free Immunoglobulin Light Chain, Kappa 10.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.99 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 1.51 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 530 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 4.24 mmol/L.
- Day 701 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 8.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.256 mg/dL; Immunoglobulin G 8.86 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.72 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 672 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 4.95 mmol/L.
- Day 785: Hemoglobin 4.84 mmol/L; Leukocytes 4.37 ×10⁹/L; Absolute Neutrophil 2.47 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 734 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.01 mmol/L.
- Day 897 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.05 mg/dL; Immunoglobulin G 7.57 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 4.7 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 707 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.23 mmol/L.
- Day 967 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.4 mg/dL; Immunoglobulin G 8.31 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.79 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 743 µmol/L; Blood Urea Nitrogen 17.1 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.72 mmol/L.
- Day 1,037 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 9.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.93 mg/dL; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.51 g/L; Beta 2 Microglobulin 33.2 µg/mL; Hemoglobin 6.08 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 194 ×10⁹/L; Blood Urea Nitrogen 16.4 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 1,142 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 8.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.1 mg/dL; Immunoglobulin G 7.84 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 19.8 µg/mL; Hemoglobin 6.7 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 751 µmol/L; Blood Urea Nitrogen 18.9 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.68 mmol/L.
- Day 1,256: Hemoglobin 5.7 mmol/L; Leukocytes 2.55 ×10⁹/L; Absolute Neutrophil 0.95 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 584 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.15 mmol/L; Albumin 34 g/L; Total Protein 5 g/dL; Glucose 4.18 mmol/L.

Other clinical attributes
- Day 0: Weight: 89 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.

Biospecimens (2 samples)
- Sample MMRF_1425_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1425_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
